Somatic mutation profile of tumor specimen TCGA-29-1775-01A (aliquot TCGA-29-1775-01A-01W-0639-09) from TCGA case TCGA-29-1775, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 51.9 years (18,943 days).
Specimen TCGA-29-1775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c142ec89-6484-40ea-8c8a-a22eae608f36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1775-10A (Blood Derived Normal), aliquot TCGA-29-1775-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e77e9e4-0d38-449e-b8c7-699aebbbbc88

The open-access MAF lists 129 somatic variants for this specimen: 97 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 27, Splice Site 5, Nonsense Mutation 5, Frame Shift Del 4, RNA 3, Splice Region 2, Intron 1, In Frame Del 1, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 61/68 reads (90%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.158T>A p.V53E | Missense Mutation (SNP) | VAF 73/128 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV52629847; called by muse, mutect2, varscan2
- AASS | c.981T>G p.S327R | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100741759; called by muse, mutect2
- AHCTF1 | c.6644A>C p.Q2215P (on ENST00000366508; = p.Q2189P on NM_015446.5) | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV58253735; called by muse, mutect2, varscan2
- AHSP | c.308A>T p.*103Lext*9 | Nonstop Mutation (SNP) | VAF 20/37 reads (54%) | catalogued as COSV56529353; called by muse, mutect2, varscan2
- AL669918.1 | c.2122G>A p.V708M | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as rs754523851, COSV101441042; called by muse, mutect2
- AP1S2 | c.50A>T p.K17I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61307080; called by muse, mutect2, varscan2
- ARSF | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV100839495; called by muse, mutect2
- ATAD2 | c.3160G>C p.D1054H | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54885226; called by muse, mutect2, varscan2
- CANT1 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56606454; called by muse, mutect2, varscan2
- CD1A | c.326A>T p.Y109F | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV99192315; called by muse, mutect2
- CD244 | c.849+1G>A p.X283_splice (on ENST00000368033 / NM_001166663.2; = p.X278_splice on NM_016382.4) | Splice Site (SNP) | VAF 85/184 reads (46%) | catalogued as rs753458715, COSV59237089; called by muse, mutect2, varscan2
- COL4A3 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV101170233; called by muse, mutect2
- DCAF11 | c.1460G>C p.R487P | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100386727, COSV58110320; called by muse, mutect2, varscan2
- DCAF4L2 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV60479766, COSV60481411; called by muse, mutect2, varscan2
- DCDC1 | c.2762C>T p.P921L (on ENST00000597505 / NM_001367979.1; = p.P28L on NM_020869.3) | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100338152; called by muse, mutect2
- DENND2A | c.1634A>T p.Q545L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52056862; called by muse, mutect2, varscan2
- DHX9 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62361386; called by muse, mutect2, varscan2
- DNAH6 | c.1488del p.X496_splice | Splice Site (DEL) | VAF 38/196 reads (19%) | catalogued as COSV99407464; called by pindel, varscan2
- DOCK3 | c.5128C>A p.L1710M | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV56542064; called by muse, mutect2, varscan2
- DTL | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 18/264 reads (7%) | catalogued as COSV100877193; called by muse, mutect2
- ECH1 | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV99669542; called by muse, mutect2
- ECT2 | c.1786C>G p.P596A (on ENST00000392692 / NM_001349098.2; = p.P565A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51692724; called by muse, mutect2, varscan2
- EFTUD2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1487772387, COSV68184358; called by mutect2, varscan2
- EGLN1 | c.746A>T p.K249M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV64150225; called by muse, varscan2
- FGGY | c.906C>T p.I302= | Splice Region (SNP) | VAF 28/97 reads (29%) | catalogued as COSV58027115; called by muse, mutect2, varscan2
- GAB2 | c.1949A>G p.K650R (on ENST00000361507 / NM_080491.3; = p.K612R on NM_012296.3) | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV60870253; called by muse, mutect2, varscan2
- GNA14 | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100502853; called by muse, mutect2
- GPRIN3 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147735218; called by muse, mutect2, varscan2
- GRIA2 | c.460A>C p.S154R | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV52401811; called by muse, mutect2, varscan2
- HAUS3 | c.1228C>A p.Q410K | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV54723774; called by muse, mutect2, varscan2
- HDAC6 | c.2272G>A p.G758S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as COSV61930112; called by muse, mutect2, varscan2
- HDC | c.1763A>G p.N588S | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV51077823; called by muse, mutect2, varscan2
- HK2 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750043718, COSV51878309; called by muse, mutect2, varscan2
- HLA-E | c.650A>C p.D217A | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV64927804; called by muse, mutect2, varscan2
- IDO1 | c.174A>T p.R58S | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV53715872; called by muse, mutect2, varscan2
- JAKMIP2 | c.1198C>G p.Q400E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV54612773; called by muse, mutect2, varscan2
- KLHDC7A | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as COSV68770686; called by muse, mutect2, varscan2
- KRTAP5-6 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.982); catalogued as COSV66289346; called by muse, mutect2, varscan2
- LAD1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.234); catalogued as COSV66213117; called by muse, mutect2, varscan2
- LAMC3 | c.1960G>T p.V654F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100736035, COSV63094447; called by muse, mutect2, varscan2
- LHX8 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV53959202; called by muse, mutect2, varscan2
- LRBA | c.3820C>T p.L1274F | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.143); catalogued as COSV100841430; called by muse, mutect2
- LRFN2 | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57832690; called by muse, mutect2, varscan2
- MAIP1 | c.31T>A p.F11I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.013); catalogued as COSV54461399; called by muse, mutect2, varscan2
- MATR3 | c.60C>G p.D20E | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV63079098; called by muse, mutect2, varscan2
- MITF | c.1333_1341del p.D445_T447del (on ENST00000448226 / NM_006722.3; = p.D345_T347del on NM_000248.4) | In Frame Del (DEL) | VAF 23/100 reads (23%) | catalogued as COSV58834841; called by mutect2, pindel, varscan2
- MMP27 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV52782216; called by muse, mutect2, varscan2
- MRPL44 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV51314265; called by muse, mutect2, varscan2
- MRPS23 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV58032783; called by muse, mutect2, varscan2
- MSH2 | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs767318526, COSV51883377; called by muse, mutect2, varscan2
- NAGPA | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | PolyPhen probably damaging (1); catalogued as COSV56570640; called by muse, mutect2, varscan2
- NAT10 | c.1039C>G p.L347V | Missense Mutation (SNP) | VAF 5/133 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1365312882, COSV57664514; called by muse, mutect2
- NEB | c.3822G>A p.M1274I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1381684600, COSV104384209, COSV99421094; called by muse, mutect2
- NIPBL | c.3559A>T p.K1187* | Nonsense Mutation (SNP) | VAF 30/96 reads (31%) | catalogued as COSV56961669; called by muse, mutect2, varscan2
- NPSR1 | c.806A>T p.K269I | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100706212; called by muse, mutect2
- NRXN2 | c.3059C>A p.S1020Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55460919; called by muse, mutect2, varscan2
- OR4N2 | c.401C>A p.T134N | Missense Mutation (SNP) | VAF 164/656 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV60053972; called by muse, mutect2, varscan2
- OR5L2 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs989252995, COSV65723889, COSV65724874; called by muse, mutect2, varscan2
- PCDHA10 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100251962, COSV56535241; called by muse, mutect2, varscan2
- PPAT | c.433A>T p.S145C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV51706096; called by muse, mutect2, varscan2
- PRICKLE2 | c.2324C>G p.A775G (on ENST00000295902; = p.A719G on NM_198859.4) | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.281); catalogued as COSV55770450; called by muse, mutect2, varscan2
- RC3H1 | c.1221G>A p.Q407= | Splice Region (SNP) | VAF 29/115 reads (25%) | catalogued as COSV51210945; called by muse, mutect2, varscan2
- RIMS1 | c.2828A>C p.Q943P | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV53476204; called by muse, mutect2, varscan2
- RXRG | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.339); catalogued as COSV63232838; called by muse, mutect2, varscan2
- SCN11A | c.1114A>C p.T372P | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV56575806; called by muse, mutect2, varscan2
- SLC36A4 | c.1469C>G p.P490R | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as COSV58397313; called by muse, mutect2, varscan2
- SLC44A5 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100901578, COSV63771932; called by muse, mutect2, varscan2
- SNX16 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100629589; called by muse, mutect2
- SPAG17 | c.6038C>A p.T2013N | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV60465252; called by muse, mutect2, varscan2
- SUB1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1173960409, COSV54083248; called by muse, mutect2, varscan2
- TBPL2 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55973007; called by muse, mutect2, varscan2
- TBXAS1 | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV99695217; called by muse, mutect2
- TRAM2 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.977); catalogued as COSV51734314; called by muse, mutect2, varscan2
- TRHR | c.1045A>T p.S349C | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV61235937; called by muse, mutect2, varscan2
- TROAP | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV57743896, COSV99226810; called by muse, mutect2
- TTC13 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV64169590; called by muse, mutect2, varscan2
- TTC23L | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV72206030; called by muse, mutect2, varscan2
- TWSG1 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 7/130 reads (5%) | catalogued as COSV50815575; called by muse, mutect2
- USP14 | c.1470G>C p.E490D | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV55276979; called by muse, mutect2, varscan2
- USP37 | c.2450A>C p.Q817P | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV51446372; called by muse, mutect2, varscan2
- VPS45 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100964892; called by muse, mutect2
- VWF | c.7474G>T p.G2492* | Nonsense Mutation (SNP) | VAF 6/112 reads (5%) | catalogued as COSV99778863; called by muse, mutect2
- WNK3 | c.3086G>T p.G1029V | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV100671256; called by muse, mutect2, varscan2
- WNK3 | c.3085G>T p.G1029C | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV100671260; called by muse, mutect2, varscan2
- ZNF227 | c.469A>G p.K157E | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.186); catalogued as COSV57313383; called by muse, varscan2
- ZNF573 | c.815A>C p.K272T (on ENST00000536220 / NM_001172692.1; = p.K214T on NM_152360.3) | Missense Mutation (SNP) | VAF 76/331 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59827606; called by muse, mutect2, varscan2
- AC004593.2 | c.402-8_416del p.X134_splice | Splice Site (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- CHML | c.1610_1620del p.E537Gfs*15 | Frame Shift Del (DEL) | VAF 48/171 reads (28%) | called by mutect2, pindel, varscan2
- HS6ST2 | c.1027_1046del p.T343Cfs*20 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- IMPDH1 | c.499G>A p.E167K (on ENST00000470772 / NM_001142573.2; = p.E253K on NM_000883.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2
- PIGU | c.251_255+6del p.X84_splice | Splice Site (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- POLR2A | c.3262G>A p.G1088R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RYR3 | c.4097_4098del p.T1366Sfs*8 | Frame Shift Del (DEL) | VAF 40/61 reads (66%) | called by pindel, varscan2
- SLC15A1 | c.1155_1179del p.L386Kfs*7 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | called by mutect2, pindel, varscan2
- SLC25A43 | c.691-6_710del p.X231_splice | Splice Site (DEL) | VAF 24/130 reads (18%) | called by mutect2, pindel
- ZSWIM5 | c.2670G>T p.W890C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- AC098582.1 | c.2844G>A p.S948= | Silent (SNP) | VAF 101/155 reads (65%) | catalogued as rs150630116; called by muse, mutect2, varscan2
- ANO7 | c.333C>T p.D111= (on ENST00000274979; = p.D56= on NM_001001666.4) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV51477121; called by muse, mutect2, varscan2
- CNTNAP2 | c.1098T>C p.F366= | Silent (SNP) | VAF 30/224 reads (13%) | catalogued as COSV62237765; called by muse, mutect2, varscan2
- COL6A3 | c.24C>T p.P8= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV55103242; called by muse, mutect2, varscan2
- GSDMC | c.1431G>A p.L477= | Silent (SNP) | VAF 48/300 reads (16%) | catalogued as COSV52698066; called by muse, mutect2, varscan2
- GUCY2C | c.2421G>A p.K807= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV99663567; called by muse, mutect2
- H2BC18 | c.165C>T p.I55= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV100516087; called by muse, mutect2
- HS2ST1 | c.564G>A p.R188= | Silent (SNP) | VAF 49/85 reads (58%) | catalogued as COSV63352222; called by muse, mutect2, varscan2
- LRBA | c.7491A>T p.P2497= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as COSV63961821; called by muse, mutect2, varscan2
- MAB21L2 | c.1026C>A p.T342= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV58263062; called by muse, mutect2, varscan2
- MARK1 | c.2295G>A p.L765= | Silent (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- MSTN | c.345G>T p.T115= | Silent (SNP) | VAF 77/174 reads (44%) | catalogued as rs1366600922, COSV53620275, COSV53621837, COSV53622113; called by muse, mutect2, varscan2
- NCAPD3 | c.3093C>T p.D1031= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV73244909; called by muse, mutect2, varscan2
- OR8K3 | c.612T>A p.A204= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as COSV100449749; called by muse, mutect2
- PIK3CG | c.1365G>A p.K455= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100782954, COSV63250841, COSV63252035; called by muse, mutect2, varscan2
- PTPRN | c.1479G>T p.L493= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV55351187; called by muse, mutect2, varscan2
- RBMS3 | c.234C>A p.I78= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV56130294; called by muse, mutect2, varscan2
- RCOR3 | c.1026G>A p.Q342= | Silent (SNP) | VAF 40/242 reads (17%) | catalogued as COSV65366569; called by muse, mutect2, varscan2
- TC2N | c.1146A>C p.S382= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV61747875; called by muse, mutect2, varscan2
- TEX2 | c.1161G>A p.G387= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV99367027; called by muse, mutect2
- TPP1 | c.1374C>G p.G458= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100196337; called by muse, mutect2, varscan2
- TRIM31 | c.1152T>C p.S384= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV65060136; called by muse, mutect2, varscan2
- TTN | c.53247C>A p.L17749= (on ENST00000591111; = p.L10325= on NM_003319.4) | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV100597103, COSV60264715; called by muse, mutect2, varscan2
- WFDC12 | c.102C>T p.C34= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV65661297; called by muse, mutect2, varscan2
- XIRP2 | c.6900G>C p.T2300= (on ENST00000628543; = p.T2475= on NM_152381.6) | Silent (SNP) | VAF 74/361 reads (20%) | catalogued as COSV54699095, COSV54725529; called by muse, mutect2, varscan2
- ZC3H4 | c.228C>T p.S76= | Silent (SNP) | VAF 101/111 reads (91%) | catalogued as rs779840948, COSV53414326; called by muse, mutect2, varscan2
- ZNF157 | c.1299G>A p.R433= | Silent (SNP) | VAF 9/162 reads (6%) | catalogued as COSV100998490; called by muse, mutect2
- C3P1 | n.2598C>G | RNA (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446390 C>A | 3'Flank (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
- MIR124-2 | n.93C>A | RNA (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- RUSC1 | c.-87+78A>C | Intron (SNP) | VAF 17/30 reads (57%) | catalogued as rs1490038540, COSV52741878; called by muse, mutect2, varscan2
- SNORD113-5 | n.11A>T | RNA (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
